CCDI case PBCBDE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/20e053ca-88c0-47d2-b372-d2b08f44f939

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,116 days).

Biospecimens (3 samples)
- Sample 0DPDH9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPDHJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPDI4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
